Gene-level copy-number profile of tumor specimen TCGA-CG-4304-01A from TCGA case TCGA-CG-4304, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 84.9 years (31,017 days).
Specimen TCGA-CG-4304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b142e11f-954b-4500-8e61-f198d902dede.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4304-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/87cc3547-6e9e-4269-9980-66446ed40b78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 177; copy number 1: 9,522; copy number 2: 43,986; copy number 3: 5,680; copy number 4: 280; copy number 5: 165.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4304-01A-01D-1155-01): tumor purity 0.58, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 160 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,955,503–202,928,636, 39 genes (within-gene range 0–1): TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2, SNORA70, SYT2, AC104463.2, AC104463.1, KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6, MGAT4EP, TUBA5P, ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA.
- chr5:91,843,687–93,091,768, 12 genes: PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1.
- chr5:119,629,559–119,681,080, 3 genes: FAM170A, TUBAP15, AC008550.1.
- chr9:4,984,390–5,629,748, 26 genes (within-gene range 0–1): JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2.
- chr9:10,829,752–12,058,227, 7 genes (within-gene range 0–2): IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1.
- chr9:20,999,509–22,029,594, 46 genes (within-gene range 0–1): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.
- chr10:87,859,158–87,994,695, 5 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1.
- chr13:61,805,150–62,029,572, 3 genes: RAC1P8, AL353765.1, LINC00358.
- chr13:85,968,999–87,892,472, 19 genes: MOB1AP1, AL354994.1, FO624990.1, DDX6P2, AL445207.1, TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 165 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:84,275,457–88,803,716, 79 genes, copy number 5 (broad region; genes not listed).
- chr9:90,801,787–91,213,046, 10 genes, copy number 5 (within-gene range 3–5): SYK, AL162585.1, AL355607.1, AL355607.2, AL158071.3, AL158071.2, LINC00484, LINC00484, AL158071.1, AL158071.4.
- chr14:22,123,318–22,509,406, 62 genes, copy number 5 (broad region; genes not listed).
- chr20:22,220,554–23,030,785, 14 genes, copy number 5: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1.

Autosomal genes at a single copy (total copy number 1): 7,118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
